Somatic mutation profile of tumor specimen TARGET-30-PARXLN-01A (aliquot TARGET-30-PARXLN-01A-01D) from TARGET case TARGET-30-PARXLN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Mediastinum, NOS; Age at diagnosis: 0.6 years (218 days).
Specimen TARGET-30-PARXLN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f3dbe5ce-256e-41fc-afe1-7d9784ff5d9e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARXLN-10A (Blood Derived Normal), aliquot TARGET-30-PARXLN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae25c4e7-4731-4b7a-9d29-7cd1769d6032

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3824G>A p.R1275Q | Missense Mutation (SNP) | VAF 14/68 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994087, CM085230, COSV66555567, COSV66558183; ClinVar: pathogenic / likely pathogenic /  risk factor; called by muse, mutect2, varscan2
- ALK | c.3520T>A p.F1174I | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs281864719, CM113795, COSV66556166, COSV66559314, COSV66568713; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BANP | c.869G>T p.R290L (on ENST00000286122; = p.R259L on NM_017869.4) | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2
